Gene-level copy-number profile of tumor specimen ALCH-B21S-TTP1-A from ALCHEMIST case ALCH-B21S, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 49.8 years (18,188 days).
Specimen ALCH-B21S-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 9d84de1b-4c7a-4870-b128-0b1ec4a64c82.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B21S-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,751 have no estimate.
https://portal.gdc.cancer.gov/files/8c8d5dc7-4c6b-4568-815f-b7a60e3832fe

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 28; copy number 1: 11,066; copy number 2: 46,533; copy number 3: 1,244; copy number 4: 1.

Homozygous deletions (total copy number 0; autosomes only): 16 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:138,123,713–138,132,390, 2 genes: A4GNT, AC023049.1.
- chr9:21,802,636–22,029,594, 8 genes (within-gene range 0–1): MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A.
- chr9:21,995,482–22,012,536, 3 genes (within-gene range 0–1): AL449423.1, CDKN2B, UBA52P6.
- chr9:39,748,514–39,874,562, 3 genes: GLIDR, BX664615.1, BX664615.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 8,260. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
